Somatic mutation profile of tumor specimen TCGA-CN-5359-01A (aliquot TCGA-CN-5359-01A-01D-1434-08) from TCGA case TCGA-CN-5359, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.8 years (21,858 days).
Specimen TCGA-CN-5359-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d715ff4-fd03-45d2-964f-dc5edb288fc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5359-10A (Blood Derived Normal), aliquot TCGA-CN-5359-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bd6fe1d-a44f-4ae0-884a-1c7c4f4e0f0b

The open-access MAF lists 152 somatic variants for this specimen: 114 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 35, Nonsense Mutation 7, Splice Site 3, In Frame Del 3, Intron 2, Frame Shift Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 13/108 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV50287934; called by muse, mutect2, varscan2
- ACTG2 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.067); catalogued as COSV100608910; called by muse, mutect2, varscan2
- ADAMTS5 | c.2720G>A p.R907Q | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs75336666, COSV53177079; called by muse, mutect2, varscan2
- ADARB2 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV101186729; called by muse, mutect2, varscan2
- AKAP9 | c.11072A>C p.K3691T (on ENST00000359028; = p.K3667T on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100662076; called by muse, mutect2, varscan2
- ANGPTL4 | c.931C>A p.Q311K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100035036; called by muse, mutect2
- APLNR | c.607G>C p.V203L | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99951293, COSV99951775; called by muse, mutect2, varscan2
- ARHGEF17 | c.5311G>A p.A1771T | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV99735037; called by muse, mutect2, varscan2
- ATP13A3 | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV99756501; called by muse, mutect2
- BCL10 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100997759; called by muse, mutect2, varscan2
- BLZF1 | c.718A>T p.N240Y | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV100250522; called by muse, mutect2
- BRSK1 | c.1211G>A p.S404N | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV100473754; called by muse, mutect2
- BST1 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99399827; called by muse, mutect2, varscan2
- BTBD3 | c.773C>A p.S258Y | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99655689; called by muse, mutect2, varscan2
- CAMTA1 | c.4388C>G p.P1463R | Missense Mutation (SNP) | VAF 43/333 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV100347133, COSV100352049; called by muse, mutect2, varscan2
- CAPN9 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs770863143, COSV55232704; called by muse, mutect2, varscan2
- CERS4 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99250490; called by muse, mutect2, varscan2
- CFAP69 | c.961C>A p.Q321K | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.269); catalogued as COSV100289898, COSV100290007; called by muse, mutect2
- CSHL1 | c.220T>G p.S74A | Missense Mutation (SNP) | VAF 19/325 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.527); catalogued as COSV99367820; called by muse, mutect2
- CTNND2 | c.1309C>A p.L437I | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.162); catalogued as COSV100473227, COSV58917662; called by muse, mutect2
- CYP2S1 | c.1502C>G p.T501R | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.019); catalogued as rs759878389, COSV100027369, COSV59506212; called by muse, mutect2
- DACH1 | c.1101A>T p.E367D | Missense Mutation (SNP) | VAF 60/661 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.026); catalogued as COSV100497761; called by muse, mutect2
- DNAJB1 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 38/464 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1286980191, COSV99584018; called by muse, mutect2
- ECT2L | c.66G>T p.Q22H | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV100871800; called by muse, mutect2
- ELOVL6 | c.701G>T p.W234L | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV100165071; called by muse, mutect2
- ENOX1 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99815355; called by muse, mutect2
- EPCAM | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as rs887011666, CD141714, COSV99764056; called by muse, mutect2, varscan2
- EPPK1 | c.3305G>T p.C1102F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101599764, COSV73262324; called by muse, mutect2, varscan2
- EXOC5 | c.1620A>C p.L540F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV100567005; called by muse, mutect2, varscan2
- EYA1 | c.904A>C p.K302Q | Missense Mutation (SNP) | VAF 33/480 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as rs887536064, COSV100378832; called by muse, mutect2
- FAT3 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs1398809924, COSV99963144; called by muse, mutect2
- FIGNL1 | c.508C>G p.R170G | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs748147882, COSV100794844; called by muse, mutect2, varscan2
- FSTL5 | c.2239T>C p.S747P | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100053464; called by muse, mutect2, varscan2
- GRHL3 | c.1238G>A p.R413Q (on ENST00000350501 / NM_198174.3; = p.R418Q on NM_021180.3) | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52564111; called by muse, mutect2
- H3C8 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV100010048; called by muse, mutect2
- HOXB1 | c.455T>G p.F152C | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as COSV99495356; called by muse, mutect2
- HOXD1 | c.449G>A p.G150D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs1428002466, COSV100514221; called by muse, mutect2
- HPS3 | c.2436G>C p.K812N | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV56056240; called by muse, mutect2, varscan2
- KIAA1109 | c.2820G>C p.Q940H | Missense Mutation (SNP) | VAF 25/368 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV99147940; called by muse, mutect2
- KIF16B | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 17/259 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV100733916; called by muse, mutect2
- KIFC1 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100997083; called by muse, mutect2, varscan2
- KLHL1 | c.1141A>T p.M381L | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100917091; called by muse, mutect2, varscan2
- LIFR | c.851A>G p.H284R | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99663555; called by muse, mutect2
- LRP1B | c.12389G>A p.G4130E | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101252970, COSV67229281; called by muse, mutect2
- LRRC42 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100066362; called by muse, mutect2
- LRRC8E | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs753338599, COSV100142695; called by muse, mutect2, varscan2
- MAN2A1 | c.1985C>T p.S662L | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as rs746252123, COSV54846697; called by muse, mutect2
- MKRN3 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV100090881; called by muse, mutect2
- MS4A6A | c.362G>A p.S121N | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.95); PolyPhen benign (0.079); catalogued as COSV100124596; called by muse, mutect2, varscan2
- MTERF3 | c.1083G>C p.K361N | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV99749038; called by muse, mutect2, varscan2
- MTHFS | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99358102; called by muse, mutect2
- NRDC | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs970389212, COSV100703175; called by muse, mutect2
- OBSCN | c.6784G>C p.V2262L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); catalogued as COSV52813738, COSV99474782; called by muse, mutect2, varscan2
- OR10J3 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs780357437, COSV100171641; called by muse, mutect2, varscan2
- OR1Q1 | c.704G>T p.W235L | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as COSV99939195; called by muse, mutect2, varscan2
- OR4K1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as rs746069793, COSV53460594; called by muse, mutect2
- OR52B2 | c.259T>G p.F87V | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101603930, COSV101603971; called by muse, mutect2
- OR5AC2 | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 26/437 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV100684323; called by muse, mutect2
- P2RY10 | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50680422, COSV99408985; called by muse, mutect2, varscan2
- PAM | c.2741G>C p.R914T (on ENST00000438793 / NM_001319943.1; = p.R915T on NM_000919.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs763117523, COSV99173147; called by muse, mutect2, varscan2
- PI4K2A | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs140967245; called by muse, mutect2, varscan2
- PKHD1L1 | c.3272G>T p.G1091V | Missense Mutation (SNP) | VAF 41/653 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV101005633; called by muse, mutect2
- PLAA | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as rs150012469; called by muse, mutect2
- PTCH1 | c.1728+1G>T p.X576_splice | Splice Site (SNP) | VAF 26/70 reads (37%) | catalogued as COSV100107843; called by muse, mutect2, varscan2
- PTPRF | c.4647-1G>T p.X1549_splice | Splice Site (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100740716; called by muse, mutect2
- PTPRJ | c.3449A>T p.E1150V | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101394667; called by muse, mutect2
- PTPRT | c.3224C>T p.P1075L | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs775998497, COSV62005004; called by muse, mutect2, varscan2
- QTRT1 | c.716T>G p.F239C | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99139020; called by muse, mutect2
- RASGRF1 | c.3750C>A p.D1250E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as COSV101174394; called by muse, mutect2, varscan2
- RHBDF1 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs778124855, COSV99244366; called by muse, mutect2
- RHOQ | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99475696; called by muse, mutect2
- RIF1 | c.6607C>T p.R2203C | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1234254323, COSV99690245; called by muse, mutect2, varscan2
- RIMKLB | c.949T>C p.S317P | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV100223798, COSV55236711; called by muse, mutect2, varscan2
- RPUSD2 | c.1288C>A p.L430I | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV100225123; called by muse, mutect2, varscan2
- RWDD2B | c.713A>T p.E238V | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99725555; called by muse, mutect2, varscan2
- SEBOX | c.162G>A p.W54* | Nonsense Mutation (SNP) | VAF 4/67 reads (6%) | catalogued as COSV99412030; called by muse, mutect2
- SEC14L3 | c.753C>G p.N251K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs773666194, COSV99307045; called by muse, mutect2, varscan2
- SERGEF | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV99787002; called by muse, mutect2, varscan2
- SLAMF8 | c.448T>A p.L150M | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99222737; called by muse, mutect2
- SLC10A3 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as COSV99682039; called by muse, mutect2, varscan2
- SLC25A27 | c.924G>A p.W308* | Nonsense Mutation (SNP) | VAF 17/130 reads (13%) | catalogued as rs1377462927, COSV100992976; called by muse, mutect2, varscan2
- SLFN13 | c.2351C>A p.T784N | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV99539830; called by muse, varscan2
- SMURF1 | c.233T>G p.I78S | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100742396; called by muse, mutect2, varscan2
- SNTG1 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 49/358 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs762384621, COSV52450357, COSV99382086; called by muse, mutect2, varscan2
- SPTLC2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | catalogued as COSV99377306; called by muse, mutect2
- SULT1E1 | c.533G>C p.W178S | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99894786; called by muse, mutect2, varscan2
- TBCK | c.2570A>T p.E857V (on ENST00000273980 / NM_001163436.4; = p.E794V on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV99912203; called by muse, mutect2, varscan2
- TFEC | c.180+2T>C p.X60_splice | Splice Site (SNP) | VAF 20/284 reads (7%) | catalogued as rs1436054502, COSV99624099; called by muse, mutect2
- TJP3 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 26/299 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs1231384189; called by muse, mutect2
- TLE5 | c.269C>G p.A90G | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV99682254; called by muse, mutect2
- TNPO3 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99602566; called by muse, mutect2
- TP53 | c.602T>A p.L201* | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as COSV52837759, COSV53037685; called by muse, mutect2, varscan2
- TRBV27 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs372917970; called by muse, mutect2
- TTN | c.7451A>C p.Q2484P (on ENST00000591111; = p.Q2438P on NM_003319.4) | Missense Mutation (SNP) | VAF 15/227 reads (7%) | PolyPhen benign (0.001); catalogued as COSV100599742; called by muse, mutect2
- TTN | c.2144G>C p.R715T (on ENST00000591111; = p.R669T on NM_003319.4) | Missense Mutation (SNP) | VAF 9/106 reads (8%) | PolyPhen probably damaging (0.943); catalogued as COSV100599744; called by muse, mutect2
- TTYH1 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100001835; called by muse, mutect2
- UBAP2L | c.104A>C p.Q35P | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99670780; called by muse, mutect2
- UBLCP1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs766001563, COSV99707290; called by muse, mutect2, varscan2
- USP29 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV99517807; called by muse, mutect2
- ZFP91 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100284366; called by muse, mutect2
- ZNF229 | c.1857G>T p.Q619H | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52160011; called by muse, mutect2
- ZNF337 | c.219del p.E74Rfs*64 | Frame Shift Del (DEL) | VAF 80/571 reads (14%) | catalogued as COSV53322601; called by mutect2, pindel, varscan2
- ZNF33A | c.1184A>T p.H395L (on ENST00000458705 / NM_006974.3; = p.H396L on NM_006954.2) | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.715); catalogued as COSV100275594; called by muse, mutect2
- ZNF354B | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100482916; called by muse, mutect2, varscan2
- ZNF804A | c.3365T>A p.F1122Y | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100166818; called by muse, mutect2
- BICDL1 | c.1511del p.D504Vfs*7 | Frame Shift Del (DEL) | VAF 30/152 reads (20%) | called by mutect2, pindel, varscan2
- H2BC7 | c.196_198del p.F66del | In Frame Del (DEL) | VAF 38/392 reads (10%) | called by mutect2, pindel
- MRC1 | c.1886C>A p.A629E | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCDHGB5 | c.2179C>T p.L727F | Missense Mutation (SNP) | VAF 41/472 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2
- RNF123 | c.3773dup p.Y1258* | Nonsense Mutation (INS) | VAF 22/141 reads (16%) | called by mutect2, pindel, varscan2
- TAF15 | c.1073G>T p.W358L (on ENST00000605844 / NM_139215.3; = p.W355L on NM_003487.4) | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP5 | c.1890_1895del p.L631_G632del | In Frame Del (DEL) | VAF 28/193 reads (15%) | called by mutect2, pindel, varscan2
- VPS13C | c.3472_3486del p.N1158_Y1162del (on ENST00000644861 / NM_020821.3; = p.N1115_Y1119del on NM_017684.5) | In Frame Del (DEL) | VAF 30/338 reads (9%) | called by mutect2, pindel
- ABCC1 | c.138C>T p.L46= | Silent (SNP) | VAF 19/238 reads (8%) | catalogued as COSV100578886; called by muse, mutect2
- ADAMTS12 | c.3666C>A p.P1222= | Silent (SNP) | VAF 44/190 reads (23%) | catalogued as COSV61256861, COSV61274230; called by muse, mutect2, varscan2
- ADAMTS20 | c.303C>T p.A101= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1170445994, COSV101239038; called by muse, mutect2, varscan2
- ADAMTS5 | c.2719C>A p.R907= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as rs760152877, COSV53184371; called by muse, mutect2, varscan2
- ADH1B | c.900G>A p.Q300= | Silent (SNP) | VAF 22/315 reads (7%) | catalogued as COSV100520667; called by muse, mutect2
- ANK2 | c.2265C>T p.N755= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs765273107, COSV52159077; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANO5 | c.2271C>A p.P757= | Silent (SNP) | VAF 12/208 reads (6%) | catalogued as COSV61083720; called by muse, mutect2
- ASTN2 | c.756C>A p.I252= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV100525415; called by muse, mutect2, varscan2
- BAG2 | c.570A>G p.L190= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs775354264, COSV100443752; called by muse, mutect2, varscan2
- CCDC172 | c.279C>A p.T93= | Silent (SNP) | VAF 13/158 reads (8%) | catalogued as COSV100319676; called by muse, mutect2
- CEP89 | c.2232C>T p.G744= | Silent (SNP) | VAF 25/338 reads (7%) | catalogued as rs1410780279, COSV59868337; called by muse, mutect2
- DSG2 | c.1047C>T p.D349= | Silent (SNP) | VAF 44/160 reads (28%) | catalogued as COSV99852901; called by muse, varscan2
- ENTPD6 | c.1353G>T p.L451= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100737001; called by muse, mutect2, varscan2
- EYA2 | c.882C>T p.Y294= | Silent (SNP) | VAF 31/345 reads (9%) | catalogued as rs774631831, COSV100426572; called by muse, mutect2
- FAT1 | c.6297C>T p.V2099= | Silent (SNP) | VAF 34/321 reads (11%) | catalogued as COSV101499152; called by muse, mutect2, varscan2
- FOXN1 | c.1479G>T p.L493= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV99881053; called by muse, mutect2, varscan2
- GABRA6 | c.279G>A p.K93= | Silent (SNP) | VAF 20/262 reads (8%) | catalogued as rs745960182, COSV50877441; called by muse, mutect2
- IKZF1 | c.1452C>T p.H484= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs964937354, COSV100498098; called by muse, mutect2, varscan2
- MGAT4A | c.525C>A p.V175= | Silent (SNP) | VAF 31/328 reads (9%) | catalogued as COSV99384049; called by muse, mutect2
- NARS2 | c.1110A>G p.P370= | Silent (SNP) | VAF 11/139 reads (8%) | catalogued as rs766835169; called by muse, mutect2
- PFAS | c.3276C>T p.D1092= | Silent (SNP) | VAF 20/202 reads (10%) | catalogued as rs199846786, COSV58980181; called by muse, mutect2, varscan2
- PLG | c.852C>T p.R284= | Silent (SNP) | VAF 20/208 reads (10%) | catalogued as rs760216173, COSV51982425; called by muse, mutect2
- RASGRP3 | c.2004C>T p.D668= (on ENST00000402538 / NM_001349975.2; = p.D667= on NM_015376.2 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV101274709; called by muse, mutect2, varscan2
- RCC1 | c.693G>A p.L231= | Silent (SNP) | VAF 31/342 reads (9%) | catalogued as COSV100868071; called by muse, mutect2
- RD3 | c.273C>T p.S91= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100879198, COSV65363040; called by muse, mutect2, varscan2
- RGR | c.450C>A p.P150= | Silent (SNP) | VAF 10/133 reads (8%) | catalogued as rs141356847, COSV100812865; called by muse, mutect2
- SHROOM1 | c.2175C>T p.R725= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV100166978; called by muse, mutect2
- SIAE | c.540C>G p.T180= | Silent (SNP) | VAF 26/300 reads (9%) | catalogued as COSV99703801; called by muse, mutect2
- SLC17A8 | c.1626C>A p.P542= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100035287; called by muse, mutect2
- SV2B | c.354C>A p.A118= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV100370460; called by muse, mutect2
- USH2A | c.4533T>A p.A1511= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as COSV100230930; called by muse, mutect2
- USP53 | c.1386A>G p.Q462= | Silent (SNP) | VAF 9/196 reads (5%) | catalogued as COSV99917575; called by muse, mutect2
- ZFP36L1 | c.690T>A p.P230= | Silent (SNP) | VAF 22/263 reads (8%) | catalogued as COSV100322524; called by muse, mutect2
- ZNF366 | c.1164G>A p.R388= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV59217581; called by muse, mutect2, varscan2
- ZNF772 | c.507G>A p.Q169= | Silent (SNP) | VAF 14/210 reads (7%) | catalogued as COSV100582776; called by muse, mutect2
- CCN6 | c.-23-12T>C | Intron (SNP) | VAF 26/346 reads (8%) | catalogued as COSV100036926; called by muse, mutect2
- DST | c.4297-1326A>G | Intron (SNP) | VAF 38/254 reads (15%) | catalogued as COSV99752504; called by muse, mutect2, varscan2
- SIAH1 | chr16:48365452 G>A | 5'Flank (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100764592; called by mutect2, varscan2
